Somatic mutation profile of tumor specimen TCGA-63-A5MH-01A (aliquot TCGA-63-A5MH-01A-12D-A27K-08) from TCGA case TCGA-63-A5MH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-A5MH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66a7aacc-3233-43dc-b6ed-2aed90baf4d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MH-10A (Blood Derived Normal), aliquot TCGA-63-A5MH-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cb9e76f-3d9d-4b72-be22-ac546d29adae

The open-access MAF lists 244 somatic variants for this specimen: 190 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 51, Frame Shift Del 10, Nonsense Mutation 9, Intron 2, Splice Site 2, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 19/231 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 35/108 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.508A>C p.S170R | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554900534, CM110153, COSV100909234, COSV64301647, COSV64303094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 34/40 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660507, CM110142, COSV64288690, COSV64296946; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMEM131 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 26/32 reads (81%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.19); PolyPhen benign (0.039); catalogued as COSV51770253, COSV51770622, COSV51771645; called by muse, mutect2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 65/78 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV99418328; called by muse, mutect2, varscan2
- ABHD10 | c.626A>C p.Y209S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99844868; called by muse, mutect2, varscan2
- ADAMTS8 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 139/223 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1161846486, COSV99960255; called by muse, mutect2, varscan2
- ADAR | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1327279065, COSV52716449; called by muse, mutect2, varscan2
- AGMO | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV100693430; called by muse, mutect2, varscan2
- AHR | c.1834A>G p.M612V | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs776554950, COSV99619160; called by muse, mutect2, varscan2
- AMER1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100365174; called by muse, mutect2, varscan2
- ANKRD50 | c.3256G>T p.A1086S | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.349); catalogued as COSV101538871; called by muse, mutect2, varscan2
- AP1G1 | c.1259A>C p.D420A | Missense Mutation (SNP) | VAF 122/142 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100249971; called by muse, mutect2, varscan2
- APOB | c.3942G>T p.E1314D | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV99263180; called by muse, mutect2, varscan2
- APOBEC3B | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100213628; called by muse, mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- ATG4C | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1348848518, COSV100507781; called by muse, mutect2, varscan2
- BDKRB1 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs778928912, COSV99387707; called by muse, mutect2, varscan2
- BOD1L1 | c.9023G>T p.R3008I | Missense Mutation (SNP) | VAF 95/119 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50006293, COSV99238189; called by muse, mutect2, varscan2
- BSN | c.2796G>T p.K932N | Missense Mutation (SNP) | VAF 63/79 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771291530, COSV56524326, COSV99607058; called by muse, mutect2, varscan2
- CABP5 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53152742; called by muse, mutect2, varscan2
- CABS1 | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs896441176, COSV99908909; called by muse, mutect2, varscan2
- CACNA1A | c.2758T>A p.W920R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100800484; called by muse, mutect2
- CBLN2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV54050178, COSV99504092; called by muse, mutect2, varscan2
- CCDC136 | c.3316G>C p.E1106Q | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV99922005; called by muse, mutect2, varscan2
- CCDC61 | c.305del p.G102Afs*19 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs763812164; called by mutect2, pindel, varscan2
- CCL7 | c.299G>C p.*100Sext*16 | Nonstop Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99565440, COSV99565546; called by muse, mutect2, varscan2
- CCN3 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as COSV99422659; called by muse, mutect2
- CDH1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 106/120 reads (88%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV99931090, COSV99931619; called by muse, mutect2, varscan2
- CDH8 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 65/76 reads (86%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.484); catalogued as COSV100179230; called by muse, mutect2, varscan2
- CDH8 | c.1789T>C p.C597R | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54867043; called by muse, mutect2, varscan2
- CES1 | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV100828532; called by muse, mutect2, varscan2
- CFTR | c.2696G>C p.R899T | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99133723; called by muse, mutect2, varscan2
- CHAF1A | c.2517G>A p.W839* | Nonsense Mutation (SNP) | VAF 60/155 reads (39%) | catalogued as COSV100010759; called by muse, mutect2, varscan2
- CHPF2 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV99222694; called by muse, mutect2, varscan2
- CMYA5 | c.5597C>G p.S1866* | Nonsense Mutation (SNP) | VAF 50/56 reads (89%) | catalogued as rs754682869, COSV101483756; called by muse, mutect2, varscan2
- CNR2 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1239252701, COSV100991211; called by muse, mutect2, varscan2
- COL6A6 | c.2626C>T p.L876F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100649699, COSV62017372; called by muse, mutect2, varscan2
- CPO | c.100del p.D34Tfs*4 | Frame Shift Del (DEL) | VAF 60/94 reads (64%) | catalogued as COSV55940390; called by mutect2, pindel, varscan2
- CR1 | c.5270G>C p.G1757A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100887346; called by muse, mutect2, varscan2
- CREBBP | c.4232G>A p.G1411E | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201186078, COSV52116481, COSV52117966; called by muse, mutect2, varscan2
- CSMD3 | c.8458C>A p.P2820T (on ENST00000297405 / NM_001363185.1; = p.P2651T on NM_052900.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822296, COSV99828017; called by muse, mutect2, varscan2
- CTNNA3 | c.2335C>A p.L779M | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV101041195; called by muse, mutect2, varscan2
- CTNND2 | c.1639T>G p.W547G | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100470773; called by muse, mutect2, varscan2
- CWC25 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs1270491265; called by muse, mutect2, varscan2
- CYP2A13 | c.488C>G p.T163R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100386604, COSV57837520; called by muse, mutect2, varscan2
- DCDC2 | c.463C>G p.R155G | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101015748; called by muse, mutect2, varscan2
- DDX56 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as rs771935254, COSV51837276, COSV99345882; called by muse, varscan2
- DNAH8 | c.9445G>C p.E3149Q | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV100542940; called by muse, mutect2, varscan2
- DZIP3 | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100847570; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.143); catalogued as COSV100348809; called by muse, mutect2, varscan2
- EXOC2 | c.758C>G p.A253G | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV100032540; called by muse, mutect2, varscan2
- EYS | c.1449G>T p.L483F | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.781); catalogued as COSV100675553, COSV100677238; called by muse, mutect2, varscan2
- FAM169A | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100998287; called by muse, mutect2, varscan2
- FAM71B | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 117/136 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100261723; called by muse, mutect2, varscan2
- FAT4 | c.5986A>G p.K1996E | Missense Mutation (SNP) | VAF 113/282 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100627060; called by muse, mutect2, varscan2
- FAT4 | c.9040G>T p.D3014Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58697803; called by muse, mutect2, varscan2
- FCRL4 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.115); catalogued as COSV54859923, COSV99619175; called by muse, varscan2
- FCRL6 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs752412653, COSV58941842; called by muse, mutect2, varscan2
- FSCB | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.25); catalogued as rs958698008, COSV100468773; called by muse, mutect2
- GALNT17 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV100351906; called by muse, mutect2, varscan2
- GRHL1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV100257439; called by muse, mutect2, varscan2
- GSTA2 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1187492491, COSV101534025, COSV72415610; called by muse, mutect2, varscan2
- HCFC2 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 118/132 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57558707, COSV99982831; called by muse, mutect2, varscan2
- HMX3 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774116; called by muse, mutect2, varscan2
- HOXA10 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99385227, COSV99385620; called by muse, mutect2, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- IFNA14 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs765528025, COSV101207288; called by muse, mutect2, varscan2
- IGHV2-70 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs61732209; called by muse, mutect2, varscan2
- IL4I1 | c.1090T>C p.W364R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99680346; called by mutect2, varscan2
- INSR | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV100251223; called by muse, mutect2, varscan2
- IZUMO1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs1163889275, COSV99710416; called by muse, mutect2, varscan2
- JAG2 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.554); catalogued as COSV100077807; called by muse, mutect2, varscan2
- KBTBD8 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 67/79 reads (85%) | catalogued as COSV55129787, COSV99805170; called by muse, mutect2, varscan2
- KCNA4 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as COSV60252496; called by muse, mutect2, varscan2
- KCNJ4 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.074); catalogued as rs1392241257, COSV100340966, COSV57856395; called by muse, mutect2, varscan2
- KHSRP | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV101231121; called by muse, mutect2, varscan2
- KIF19 | c.2377C>G p.L793V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs758525276, COSV100738893; called by muse, mutect2
- KNTC1 | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100337849; called by muse, mutect2, varscan2
- KPNA1 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1281829451, COSV60270105; called by muse, mutect2, varscan2
- KY | c.19A>T p.I7F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.053); catalogued as COSV101414934; called by muse, mutect2, varscan2
- LENG9 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs766062750, COSV56617702, COSV56619615; called by muse, mutect2
- LRRIQ4 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.937); catalogued as COSV100540047, COSV61619792; called by muse, mutect2, varscan2
- LYST | c.2844C>G p.S948R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as rs767380219, COSV101087894; called by muse, mutect2, varscan2
- MACO1 | c.365T>C p.L122S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100974973; called by muse, mutect2, varscan2
- MAPRE1 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV100980380; called by muse, mutect2, varscan2
- MARK4 | c.1912G>A p.E638K (on ENST00000262891 / NM_001199867.2; = p.L664= on NM_031417.4) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.202); catalogued as COSV99487778; called by muse, mutect2, varscan2
- MDFI | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs142795908; called by muse, mutect2, varscan2
- MIB1 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99838265; called by muse, mutect2, varscan2
- MOGS | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV99270228; called by muse, mutect2, varscan2
- NEXMIF | c.1349A>T p.Y450F | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1569335723, COSV99279390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIBAN3 | c.2063T>C p.V688A | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99394783; called by muse, mutect2
- NLRP11 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100789615; called by muse, mutect2, varscan2
- NLRP13 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.097); catalogued as COSV61622964; called by muse, mutect2, varscan2
- NLRP2 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99671795; called by muse, mutect2, varscan2
- NPHS1 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM097349, COSV100799561; called by muse, mutect2, varscan2
- NUAK2 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV65682539; called by muse, mutect2, varscan2
- NUPR1 | c.67A>T p.S23C | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); catalogued as COSV100257117, COSV61405180; called by muse, mutect2, varscan2
- NVL | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV99893540; called by muse, mutect2, varscan2
- OPRPN | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV101271070; called by muse, mutect2
- OR13C3 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753678810, COSV101053233, COSV66166217; called by muse, mutect2, varscan2
- OR4D6 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100271513; called by muse, mutect2, varscan2
- OR52E2 | c.734A>G p.H245R | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1427258636, COSV100384578; called by muse, mutect2, varscan2
- PARP6 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV99535697; called by muse, mutect2, varscan2
- PCSK7 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 49/51 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309113; called by muse, mutect2, varscan2
- PDCD1 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100545286; called by muse, mutect2, varscan2
- PDE10A | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV100604227; called by muse, mutect2, varscan2
- PDE4D | c.2052G>C p.E684D (on ENST00000340635 / NM_001104631.2; = p.E548D on NM_006203.4) | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100401303; called by muse, mutect2, varscan2
- PER1 | c.3259+1G>A p.X1087_splice | Splice Site (SNP) | VAF 66/86 reads (77%) | catalogued as rs751982800, COSV57920729; called by muse, mutect2, varscan2
- PFKL | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV62463714; called by muse, mutect2, varscan2
- PHACTR4 | c.1429G>A p.D477N (on ENST00000373839 / NM_001350159.2; = p.D487N on NM_023923.4) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs543331485, COSV65784299; called by muse, mutect2, varscan2
- PHLPP2 | c.3864A>T p.E1288D | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV100673454; called by muse, mutect2, varscan2
- PI4KA | c.3164A>G p.K1055R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.162); catalogued as COSV99743951; called by muse, mutect2
- PLSCR5 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101494460; called by muse, mutect2, varscan2
- PLXNA4 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as COSV100322080; called by muse, mutect2, varscan2
- POTED | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.788); catalogued as COSV100202960, COSV100203242; called by muse, mutect2, varscan2
- PRRC2A | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs781324096, COSV101050978; called by muse, mutect2, varscan2
- RAX | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99900157; called by muse, mutect2, varscan2
- RBM39 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 83/103 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV53615214, COSV53616264, COSV99488189; called by muse, mutect2, varscan2
- REG1B | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs771580503, COSV100521247; called by muse, mutect2, varscan2
- REPS1 | c.1231T>C p.W411R | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV99238335; called by muse, mutect2, varscan2
- RETREG3 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99258309; called by muse, varscan2
- RGS7 | c.1319G>T p.R440I | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100463890; called by muse, mutect2, varscan2
- RMDN3 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV99539723; called by muse, mutect2, varscan2
- RNF113B | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99940262; called by muse, mutect2, varscan2
- SAMD15 | c.202del p.E68Sfs*10 | Frame Shift Del (DEL) | VAF 66/113 reads (58%) | catalogued as rs1199968035; called by mutect2, pindel, varscan2
- SCN2A | c.5598G>T p.L1866F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99329866; called by muse, mutect2, varscan2
- SCN9A | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311071; called by muse, mutect2, varscan2
- SEMA5B | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs747557471, COSV52103187; called by muse, mutect2, varscan2
- SF3B3 | c.1652A>T p.Q551L | Missense Mutation (SNP) | VAF 75/93 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV100209534; called by muse, mutect2, varscan2
- SIAH2 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV100469063; called by muse, mutect2, varscan2
- SLC1A4 | c.1449G>C p.K483N | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52235936, COSV99308776; called by muse, mutect2, varscan2
- SLC6A4 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs753300083, COSV99911161; called by muse, mutect2, varscan2
- SMARCAD1 | c.1323G>C p.L441F | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100758687; called by muse, mutect2, varscan2
- SMYD3 | c.307C>T p.R103* (on ENST00000490107 / NM_001375962.1; = p.R44* on NM_022743.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 76/209 reads (36%) | catalogued as rs772756510, COSV101193518; called by muse, mutect2, varscan2
- SPAG17 | c.6634C>A p.L2212I | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV100307646; called by muse, mutect2, varscan2
- SPANXD | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as COSV65153249; called by muse, mutect2, varscan2
- SPON1 | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 15/17 reads (88%) | catalogued as COSV100115132; called by muse, mutect2, varscan2
- SRGAP3 | c.2048T>C p.I683T | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV100840649; called by muse, mutect2, varscan2
- SRPRB | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101524150; called by muse, mutect2, varscan2
- STAB2 | c.6340T>A p.Y2114N | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185573; called by muse, mutect2, varscan2
- STAB2 | c.6341A>T p.Y2114F | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101185574; called by muse, mutect2, varscan2
- STON1 | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV100561382; called by muse, mutect2
- SYNE2 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs944787012, COSV100419995; called by muse, mutect2, varscan2
- SYTL4 | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99342605; called by muse, mutect2, varscan2
- TAFA2 | c.323A>T p.K108I | Missense Mutation (SNP) | VAF 105/117 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101352717; called by muse, mutect2, varscan2
- TAGLN3 | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1305873843, COSV56330035, COSV99845271; called by muse, mutect2, varscan2
- TAS1R3 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100229190; called by muse, mutect2, varscan2
- TCHH | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 177/588 reads (30%) | catalogued as COSV100914872, COSV64272629; called by muse, mutect2, varscan2
- TEX15 | c.2461G>A p.D821N (on ENST00000256246; = p.D1204N on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV99820627; called by muse, mutect2, varscan2
- TKTL2 | c.1457C>T p.T486I | Missense Mutation (SNP) | VAF 65/85 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs369100318, COSV99761036; called by muse, mutect2, varscan2
- TMEM70 | c.592A>C p.N198H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100383973; called by muse, mutect2, varscan2
- TNN | c.1267G>T p.V423L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as COSV53427763, COSV99510948; called by muse, mutect2, varscan2
- TNXB | c.4361G>T p.G1454V (on ENST00000647633; = p.G1207V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100925708; called by muse, mutect2, varscan2
- TNXB | c.4360G>A p.G1454R (on ENST00000647633; = p.G1207R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100925709; called by muse, mutect2, varscan2
- TRAK1 | c.591G>T p.R197S (on ENST00000327628 / NM_001349247.2; = p.R139S on NM_014965.5) | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.49); PolyPhen benign (0.114); catalogued as COSV100409695; called by muse, mutect2, varscan2
- TRAPPC10 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52377908; called by muse, mutect2, varscan2
- TRIM36 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 68/83 reads (82%) | catalogued as COSV99142229; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV100708824; called by muse, mutect2, varscan2
- TUBG1 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99258312; called by muse, mutect2, varscan2
- TUBG1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99258318; called by muse, varscan2
- UGT2B15 | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100592197; called by muse, mutect2, varscan2
- UHRF1BP1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99511355; called by muse, mutect2, varscan2
- UNC5D | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54820685, COSV99771504, COSV99775624; called by muse, mutect2, varscan2
- USH2A | c.9533C>G p.S3178C | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100228067, COSV56353278; called by muse, mutect2, varscan2
- USP29 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.197); catalogued as rs749178321, COSV54143731, COSV54146163; called by muse, mutect2, varscan2
- VIP | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV100923892, COSV65889741; called by muse, mutect2
- VPS13B | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1209759817, COSV100660633; called by muse, mutect2, varscan2
- VPS13B | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs368241718; called by muse, mutect2, varscan2
- WDR64 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100843603; called by muse, mutect2, varscan2
- XKR3 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.057); catalogued as COSV100509101; called by muse, mutect2, varscan2
- YTHDC2 | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs935385854, COSV99362824; called by muse, mutect2, varscan2
- ZBTB32 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99385830; called by muse, mutect2, varscan2
- ZMAT1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as rs1264342873, COSV100858647; called by muse, mutect2, varscan2
- ZNF17 | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100299881; called by muse, mutect2, varscan2
- ZNF208 | c.2114C>G p.S705C | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV101236699; called by muse, varscan2
- ZNF419 | c.1411G>C p.V471L | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55658767; called by muse, mutect2, varscan2
- ZNF638 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100037858; called by muse, mutect2, varscan2
- ZNF99 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV68057967; called by muse, mutect2, varscan2
- ACAA1 | c.1089del p.E364Rfs*3 | Frame Shift Del (DEL) | VAF 46/72 reads (64%) | called by mutect2, pindel, varscan2
- ACACA | c.611-1G>A p.X204_splice | Splice Site (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- HDAC9 | c.1615_1622del p.L539Sfs*14 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | called by mutect2, pindel, varscan2
- HOXA3 | c.1031del p.P344Rfs*32 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAPK8IP2 | c.2267del p.N756Tfs*24 | Frame Shift Del (DEL) | VAF 60/207 reads (29%) | called by mutect2, pindel, varscan2
- OR51B5 | c.53_54delinsC p.L18Sfs*56 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by pindel, varscan2*
- PPFIA2 | c.1465del p.A489Lfs*3 | Frame Shift Del (DEL) | VAF 98/150 reads (65%) | called by mutect2, pindel, varscan2
- ZNF280B | c.1380_1389del p.H460Qfs*8 | Frame Shift Del (DEL) | VAF 57/160 reads (36%) | called by mutect2, pindel, varscan2
- APBB1IP | c.198T>C p.A66= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as COSV100774277; called by muse, mutect2, varscan2
- ARHGAP25 | c.1449C>T p.H483= (on ENST00000409202 / NM_001007231.3; = p.H475= on NM_014882.3) | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV99770928; called by muse, mutect2, varscan2
- ARHGAP5 | c.1995T>C p.I665= | Silent (SNP) | VAF 73/86 reads (85%) | catalogued as COSV100564944; called by muse, mutect2, varscan2
- ARHGEF18 | c.1923G>A p.Q641= (on ENST00000359920 / NM_001130955.2; = p.Q537= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100148885; called by muse, varscan2
- CASP8AP2 | c.5661G>T p.V1887= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99386706; called by muse, mutect2
- CCDC54 | c.453G>A p.T151= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs142151683; called by muse, mutect2, varscan2
- CCNB1IP1 | c.177A>T p.L59= | Silent (SNP) | VAF 51/64 reads (80%) | catalogued as COSV100738462; called by muse, mutect2, varscan2
- CDH12 | c.1128G>A p.L376= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV101200839, COSV66437206; called by muse, mutect2, varscan2
- CEP250 | c.5286G>A p.L1762= | Silent (SNP) | VAF 102/119 reads (86%) | catalogued as COSV100698700; called by muse, mutect2, varscan2
- CMYA5 | c.5772G>C p.L1924= | Silent (SNP) | VAF 45/54 reads (83%) | catalogued as COSV101483757; called by muse, mutect2, varscan2
- COL11A1 | c.3006A>T p.A1002= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV100614704; called by muse, mutect2, varscan2
- CRYZ | c.372A>G p.K124= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV100558444; called by muse, mutect2, varscan2
- DAPP1 | c.582A>G p.K194= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV99596525; called by muse, varscan2
- ENPP2 | c.1662A>T p.P554= (on ENST00000075322 / NM_001040092.3; = p.P606= on NM_006209.5) | Silent (SNP) | VAF 104/239 reads (44%) | catalogued as COSV99307296; called by muse, mutect2, varscan2
- EPB41 | c.2034C>T p.I678= (on ENST00000343067 / NM_001166005.2; = p.I436= on NM_004437.4) | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs867326082, COSV58055121; called by muse, mutect2, varscan2
- FEM1B | c.1650G>A p.L550= | Silent (SNP) | VAF 85/210 reads (40%) | catalogued as COSV100183529; called by muse, mutect2, varscan2
- HCAR2 | c.306G>A p.L102= | Silent (SNP) | VAF 75/87 reads (86%) | catalogued as COSV100186399; called by muse, mutect2, varscan2
- HDAC9 | c.2445G>A p.L815= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV101285833; called by muse, mutect2, varscan2
- HOXA11 | c.105C>T p.P35= | Silent (SNP) | VAF 83/192 reads (43%) | catalogued as COSV99135840; called by muse, mutect2, varscan2
- JUN | c.768G>A p.E256= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100973360; called by muse, mutect2, varscan2
- KIR3DL1 | c.681A>C p.S227= | Silent (SNP) | VAF 8/234 reads (3%) | catalogued as COSV100428160; called by muse, mutect2
- LIFR | c.1815C>T p.I605= | Silent (SNP) | VAF 67/226 reads (30%) | catalogued as COSV99663071; called by muse, mutect2, varscan2
- MYH9 | c.1056C>T p.I352= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs727504861, COSV53388758; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOM2 | c.4221C>T p.G1407= | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as rs201012252, COSV100036467; called by muse, mutect2, varscan2
- OSBPL8 | c.2373G>A p.K791= | Silent (SNP) | VAF 73/81 reads (90%) | catalogued as COSV99674347; called by muse, mutect2, varscan2
- PADI1 | c.1329G>A p.Q443= | Silent (SNP) | VAF 61/104 reads (59%) | catalogued as rs1479754628, COSV100968964; called by muse, mutect2, varscan2
- PLEKHA5 | c.249C>T p.T83= | Silent (SNP) | VAF 221/236 reads (94%) | catalogued as COSV54694077; called by muse, mutect2, varscan2
- PRDM9 | c.2169G>A p.R723= | Silent (SNP) | VAF 193/409 reads (47%) | catalogued as COSV99689672; called by muse, varscan2
- RFXANK | c.363C>T p.D121= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs139803434; called by muse, mutect2, varscan2
- RGS6 | c.783C>A p.I261= | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as COSV100664741; called by muse, mutect2, varscan2
- RRH | c.129C>T p.N43= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100495942; called by muse, mutect2, varscan2
- SCRN1 | c.756G>A p.Q252= | Silent (SNP) | VAF 73/184 reads (40%) | catalogued as rs1483884848, COSV99620702; called by muse, mutect2, varscan2
- SELENOF | c.9G>C p.A3= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as COSV100085786; called by muse, mutect2, varscan2
- SFXN3 | c.366C>T p.F122= | Silent (SNP) | VAF 51/63 reads (81%) | catalogued as COSV99827341; called by muse, mutect2, varscan2
- SLC17A4 | c.498C>T p.L166= | Silent (SNP) | VAF 108/252 reads (43%) | catalogued as rs1228419017, COSV100930483; called by muse, mutect2, varscan2
- SLC22A10 | c.1545A>G p.L515= | Silent (SNP) | VAF 55/66 reads (83%) | catalogued as COSV100235464; called by muse, mutect2, varscan2
- SLC4A5 | c.1938C>T p.F646= | Silent (SNP) | VAF 138/348 reads (40%) | catalogued as COSV100697337; called by muse, mutect2, varscan2
- SPECC1 | c.1579C>A p.R527= | Silent (SNP) | VAF 86/97 reads (89%) | catalogued as COSV99821081; called by muse, mutect2, varscan2
- SPG21 | c.748C>T p.L250= | Silent (SNP) | VAF 98/106 reads (92%) | catalogued as COSV99200175; called by muse, mutect2, varscan2
- SRPK2 | c.567T>C p.C189= | Silent (SNP) | VAF 46/53 reads (87%) | catalogued as COSV100623697; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.738C>T p.G246= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs1365702976, COSV99833258; called by muse, mutect2, varscan2
- SUFU | c.1168C>T p.L390= | Silent (SNP) | VAF 71/80 reads (89%) | catalogued as COSV100882836; called by muse, mutect2, varscan2
- SYT13 | c.231C>G p.L77= | Silent (SNP) | VAF 67/83 reads (81%) | catalogued as COSV99194631; called by muse, mutect2, varscan2
- TBC1D4 | c.1968G>A p.L656= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100884494; called by muse, mutect2, varscan2
- TBXT | c.420C>T p.P140= | Silent (SNP) | VAF 110/203 reads (54%) | catalogued as rs376242587; called by muse, mutect2, varscan2
- TRANK1 | c.3150C>T p.F1050= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as COSV57156122; called by muse, mutect2, varscan2
- TUBG1 | c.591G>A p.Q197= | Silent (SNP) | VAF 80/194 reads (41%) | catalogued as COSV99258322; called by muse, mutect2, varscan2
- TUBG1 | c.630G>A p.L210= | Silent (SNP) | VAF 103/272 reads (38%) | catalogued as COSV99258328; called by muse, varscan2
- VAX1 | c.285G>T p.L95= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV99523924; called by muse, mutect2, varscan2
- VWF | c.3903G>T p.V1301= | Silent (SNP) | VAF 70/146 reads (48%) | catalogued as COSV99777732; called by muse, mutect2, varscan2
- ZMYND8 | c.2685G>T p.L895= (on ENST00000311275 / NM_001363741.2; = p.L869= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/76 reads (89%) | catalogued as COSV99519378; called by muse, mutect2, varscan2
- ACAD9 | c.*106C>G | 3'UTR (SNP) | VAF 15/81 reads (19%) | catalogued as rs1401827025, COSV100458889; called by muse, mutect2, varscan2
- TBRG4 | c.908-94C>G | Intron (SNP) | VAF 48/97 reads (49%) | catalogued as COSV99345220; called by muse, mutect2, varscan2
- TTN | c.10361-4763C>T | Intron (SNP) | VAF 52/65 reads (80%) | catalogued as rs1553950420, COSV100591368; ClinVar: uncertain significance; called by muse, mutect2, varscan2
